Somatic mutation profile of tumor specimen TCGA-DD-AACB-01A (aliquot TCGA-DD-AACB-01A-11D-A40R-10) from TCGA case TCGA-DD-AACB, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 74.2 years (27,103 days).
Specimen TCGA-DD-AACB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 25ad4bb6-22fb-40a0-bdbc-1a1b881381fc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-AACB-10A (Blood Derived Normal), aliquot TCGA-DD-AACB-10A-01D-A40U-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/33c7ee03-cab4-40d3-9234-a8dbecca7a3b

The open-access MAF lists 113 somatic variants for this specimen: 84 protein-altering or splice-affecting, 28 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 71, Silent 28, Frame Shift Del 8, Nonsense Mutation 2, Frame Shift Ins 2, In Frame Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.95A>G p.D32G | Missense Mutation (SNP) | VAF 33/132 reads (25%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs121913396, COSV62688001, COSV62688037, COSV62688249; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.843C>G p.D281E | Missense Mutation (SNP) | VAF 37/59 reads (63%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as rs1057519984, CM137620, COSV52664212, COSV52688790, COSV52719382, COSV53103731; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCA13 | c.11246G>A p.G3749D | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.035); catalogued as COSV101447139, COSV71284937, COSV71293911; called by muse, mutect2, varscan2
- ABCC3 | c.1936A>C p.S646R | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.467); catalogued as COSV99559599; called by muse, mutect2, varscan2
- ADARB2 | c.975G>T p.K325N | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as rs752210106, COSV101187142; called by muse, varscan2
- AGPAT2 | c.721G>T p.V241F | Missense Mutation (SNP) | VAF 51/78 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs11545228, COSV100452036; called by muse, mutect2, varscan2
- ANK2 | c.2119A>C p.K707Q | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as COSV100003375; called by muse, mutect2, varscan2
- APOB | c.1027C>T p.Q343* | Nonsense Mutation (SNP) | VAF 26/58 reads (45%) | catalogued as COSV99267171; called by muse, mutect2, varscan2
- ATP12A | c.2720A>T p.K907M | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.44); catalogued as COSV99518215; called by muse, mutect2, varscan2
- AXIN2 | c.982G>A p.G328S | Missense Mutation (SNP) | VAF 47/120 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as COSV100196833; called by muse, mutect2, varscan2
- CADPS | c.253G>A p.G85S | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99340126; called by muse, mutect2
- CASK | c.2761C>T p.P921S (on ENST00000378163 / NM_001367721.1; = p.P916S on NM_003688.3) | Missense Mutation (SNP) | VAF 27/38 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100587584; called by muse, mutect2, varscan2
- CATSPERZ | c.395T>A p.M132K | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV99134815; called by muse, mutect2, varscan2
- CD83 | c.125A>T p.Q42L | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.018); catalogued as COSV100997825; called by muse, mutect2, varscan2
- CES4A | c.1502A>C p.N501T (on ENST00000648724 / NM_001364782.1; = p.N403T on NM_001190201.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/54 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100110207; called by muse, mutect2, varscan2
- CNTN5 | c.2797T>C p.S933P | Missense Mutation (SNP) | VAF 40/135 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.478); catalogued as COSV99679840; called by muse, mutect2, varscan2
- CSMD3 | c.8083C>A p.P2695T | Missense Mutation (SNP) | VAF 23/181 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.811); catalogued as COSV99843289, COSV99845417; called by muse, mutect2, varscan2
- CUL4A | c.413G>T p.C138F (on ENST00000375440 / NM_001008895.4; = p.C38F on NM_003589.3) | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.045); catalogued as COSV100417465, COSV58371212; called by muse, mutect2, varscan2
- DDX11 | c.190G>A p.D64N | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99300063; called by muse, mutect2, varscan2
- DMRT1 | c.236G>A p.C79Y | Missense Mutation (SNP) | VAF 39/77 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101206698; called by muse, mutect2, varscan2
- DNAH7 | c.11690C>A p.T3897K | Missense Mutation (SNP) | VAF 42/138 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0.085); catalogued as COSV100416750, COSV56781534; called by muse, mutect2, varscan2
- ELAVL2 | c.40A>G p.T14A | Missense Mutation (SNP) | VAF 41/129 reads (32%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as COSV99806865; called by muse, mutect2, varscan2
- EPM2AIP1 | c.547G>A p.A183T | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as COSV99212594; called by muse, mutect2, varscan2
- EXOC7 | c.567G>T p.E189D | Missense Mutation (SNP) | VAF 58/134 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.115); catalogued as rs117225564, COSV100135582; called by muse, mutect2, varscan2
- FAM168B | c.442A>T p.M148L | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.455); catalogued as COSV101112256; called by muse, mutect2, varscan2
- FAM210A | c.433T>A p.S145T | Missense Mutation (SNP) | VAF 44/153 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100452467; called by muse, mutect2, varscan2
- FBXL7 | c.602A>T p.D201V | Missense Mutation (SNP) | VAF 62/133 reads (47%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.983); catalogued as COSV100310509; called by muse, mutect2, varscan2
- FOLH1 | c.428T>C p.L143S | Missense Mutation (SNP) | VAF 23/139 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.047); catalogued as COSV99923672; called by muse, mutect2, varscan2
- GRM4 | c.1579G>C p.G527R | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100946721; called by muse, mutect2, varscan2
- GTF2F1 | c.422A>G p.H141R | Missense Mutation (SNP) | VAF 59/85 reads (69%) | SIFT tolerated (0.22); PolyPhen benign (0.027); catalogued as COSV101081348; called by muse, mutect2, varscan2
- HSP90B1 | c.640A>G p.K214E | Missense Mutation (SNP) | VAF 22/224 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100236694; called by muse, mutect2, varscan2
- ING1 | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 65/273 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.237); catalogued as COSV100312306; called by muse, mutect2, varscan2
- ITLN1 | c.688G>A p.E230K | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.044); catalogued as COSV100406312, COSV100406369; called by muse, mutect2, varscan2
- JKAMP | c.128G>A p.G43E (on ENST00000554271 / NM_001284201.1; = p.G29E on NM_016475.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.947); catalogued as COSV54198953; called by muse, mutect2, varscan2
- KBTBD3 | c.1817G>T p.W606L | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.563); catalogued as COSV101595712; called by muse, mutect2, varscan2
- KBTBD3 | c.1816T>A p.W606R | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.951); catalogued as COSV101595713; called by muse, mutect2, varscan2
- KEAP1 | c.380del p.G127Vfs*30 | Frame Shift Del (DEL) | VAF 43/76 reads (57%) | catalogued as COSV50302392, COSV50422891; called by mutect2, pindel, varscan2
- MACF1 | c.5507A>C p.D1836A | Missense Mutation (SNP) | VAF 15/81 reads (19%) | catalogued as COSV99246113; called by muse, mutect2, varscan2
- MAP3K20 | c.319A>G p.I107V | Missense Mutation (SNP) | VAF 168/419 reads (40%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.462); catalogued as rs759664582, COSV100169386; called by muse, mutect2, varscan2
- MAST4 | c.1093T>A p.C365S (on ENST00000403625 / NM_001164664.2; = p.C176S on NM_015183.3) | Missense Mutation (SNP) | VAF 41/178 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV99845283; called by muse, mutect2, varscan2
- MUC16 | c.2557T>A p.S853T | Missense Mutation (SNP) | VAF 65/93 reads (70%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.248); catalogued as COSV101200784; called by muse, mutect2, varscan2
- NAP1L3 | c.960G>T p.K320N | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100220577, COSV59073888; called by muse, mutect2, varscan2
- NCOA5 | c.1125G>A p.M375I | Missense Mutation (SNP) | VAF 25/42 reads (60%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV99275891; called by muse, mutect2, varscan2
- NRP2 | c.130G>A p.G44S | Missense Mutation (SNP) | VAF 48/107 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757131491, COSV99785308; called by muse, mutect2, varscan2
- OR11L1 | c.964T>C p.Y322H | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV100869469; called by muse, mutect2, varscan2
- OR14A16 | c.199T>A p.L67M | Missense Mutation (SNP) | VAF 43/270 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV100713832; called by muse, mutect2, varscan2
- PBX1 | c.680G>A p.R227H | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.563); catalogued as COSV100905214; called by muse, mutect2, varscan2
- PFKFB3 | c.818G>A p.S273N | Missense Mutation (SNP) | VAF 7/46 reads (15%) | PolyPhen benign (0); catalogued as rs748570830, COSV100432249; called by muse, mutect2, varscan2
- PGLYRP2 | c.955del p.R319Dfs*8 | Frame Shift Del (DEL) | VAF 16/68 reads (24%) | catalogued as COSV52992406, COSV99483752; called by mutect2, pindel, varscan2
- PKP4 | c.937G>A p.G313R | Missense Mutation (SNP) | VAF 39/106 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV101081387; called by muse, mutect2, varscan2
- PLPPR3 | c.361T>C p.C121R | Missense Mutation (SNP) | VAF 36/52 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100608945; called by muse, mutect2, varscan2
- PRR14L | c.5557A>G p.M1853V | Missense Mutation (SNP) | VAF 91/210 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.173); catalogued as rs767249771, COSV100392657; called by muse, mutect2, varscan2
- PSAP | c.115G>A p.A39T | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101206513; called by muse, mutect2, varscan2
- PTPRB | c.5580C>G p.I1860M | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs906142386, COSV99718554; called by muse, mutect2, varscan2
- PTPRT | c.2417A>T p.K806I | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.374); catalogued as COSV100629438; called by muse, mutect2, varscan2
- RALBP1 | c.1744G>A p.E582K | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.111); catalogued as rs1156806829, COSV50041152; called by muse, mutect2, varscan2
- RGS5 | c.420G>T p.M140I | Missense Mutation (SNP) | VAF 49/144 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV100009261; called by muse, mutect2, varscan2
- RNF180 | c.854G>T p.S285I | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.293); catalogued as COSV99684880; called by muse, mutect2, varscan2
- ROBO2 | c.3599C>A p.P1200Q | Missense Mutation (SNP) | VAF 73/140 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.397); catalogued as rs376068100, COSV59925300; called by muse, mutect2, varscan2
- RPL19 | c.46C>T p.R16C | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs774934686, COSV99841541; called by muse, mutect2, varscan2
- SLC26A6 | c.1510G>T p.V504L | Missense Mutation (SNP) | VAF 75/273 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.526); catalogued as rs373135262, COSV100258627; called by muse, mutect2, varscan2
- SLCO2A1 | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as rs148547180, CM147859, COSV60483787; called by muse, mutect2, varscan2
- SP1 | c.220C>T p.P74S (on ENST00000327443 / NM_138473.3; = p.P67S on NM_003109.1) | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.774); catalogued as rs1456079816, COSV100540798; called by muse, mutect2, varscan2
- SPIRE1 | c.1411A>G p.T471A (on ENST00000409402 / NM_001128626.2; = p.T457A on NM_020148.3) | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs1295574292, COSV59161591; called by muse, mutect2, varscan2
- SRMS | c.1354C>T p.P452S | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.37); catalogued as COSV99420727; called by muse, mutect2, varscan2
- STARD13 | c.484C>A p.L162M (on ENST00000336934 / NM_001243476.3; = p.L44M on NM_052851.3) | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as COSV99716236; called by muse, mutect2
- STIL | c.1526C>T p.P509L | Missense Mutation (SNP) | VAF 49/117 reads (42%) | SIFT tolerated (0.87); PolyPhen benign (0.003); catalogued as COSV99681220; called by muse, mutect2, varscan2
- STK32B | c.883G>A p.A295T | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as rs773060917, COSV51508331; called by muse, mutect2, varscan2
- TANC1 | c.1274C>T p.S425F | Missense Mutation (SNP) | VAF 118/239 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.791); catalogued as rs1175001379, COSV55085660; called by muse, mutect2, varscan2
- TNRC18 | c.1858A>G p.K620E | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.824); catalogued as COSV101259506; called by muse, mutect2, varscan2
- TRAK1 | c.2668G>T p.V890L | Missense Mutation (SNP) | VAF 34/62 reads (55%) | SIFT tolerated (0.35); PolyPhen benign (0.011); catalogued as COSV100565797; called by muse, mutect2, varscan2
- TRPM3 | c.4685C>T p.A1562V (on ENST00000357533 / NM_001366142.2; = p.A1417V on NM_020952.6) | Missense Mutation (SNP) | VAF 53/83 reads (64%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.142); catalogued as COSV100678263; called by muse, mutect2, varscan2
- XKR9 | c.762T>A p.C254* | Nonsense Mutation (SNP) | VAF 20/229 reads (9%) | catalogued as COSV101281966; called by muse, mutect2
- ZSCAN2 | c.1460C>A p.S487Y | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.092); catalogued as COSV100306945; called by muse, mutect2, varscan2
- ACACA | c.5897del p.K1966Rfs*10 | Frame Shift Del (DEL) | VAF 41/132 reads (31%) | called by mutect2, pindel, varscan2
- BCO1 | c.176G>A p.S59N | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2
- CHGB | c.967dup p.E323Gfs*18 | Frame Shift Ins (INS) | VAF 29/179 reads (16%) | called by mutect2, pindel, varscan2
- FASN | c.758_762del p.T253Rfs*31 | Frame Shift Del (DEL) | VAF 37/89 reads (42%) | called by mutect2, pindel, varscan2
- KMT2A | c.7614_7645del p.L2539Nfs*14 | Frame Shift Del (DEL) | VAF 6/71 reads (8%) | called by pindel, varscan2*
- NAP1L5 | c.138_149del p.S46_Q50delinsR | In Frame Del (DEL) | VAF 29/39 reads (74%) | called by mutect2, pindel, varscan2
- PLCL2 | c.596dup p.N199Kfs*12 (on ENST00000615277 / NM_001144382.2; = p.N73Kfs*12 on NM_015184.5) | Frame Shift Ins (INS) | VAF 35/167 reads (21%) | called by mutect2, pindel, varscan2
- SSU72 | c.166del p.D56Ifs*52 | Frame Shift Del (DEL) | VAF 37/110 reads (34%) | called by mutect2, pindel, varscan2
- ST3GAL2 | c.179del p.L60Pfs*54 | Frame Shift Del (DEL) | VAF 17/82 reads (21%) | called by mutect2, pindel, varscan2
- USP54 | c.1088del p.P363Lfs*79 | Frame Shift Del (DEL) | VAF 20/105 reads (19%) | called by mutect2, pindel, varscan2
- ANK1 | c.4512C>T p.Y1504= | Silent (SNP) | VAF 46/69 reads (67%) | catalogued as COSV99226359; called by muse, mutect2, varscan2
- ASPM | c.8967T>C p.Y2989= | Silent (SNP) | VAF 41/102 reads (40%) | catalogued as COSV99660893; called by muse, mutect2, varscan2
- CENPT | c.1302G>A p.E434= | Silent (SNP) | VAF 16/64 reads (25%) | catalogued as COSV99535300; called by muse, mutect2, varscan2
- COPG1 | c.2211C>T p.P737= | Silent (SNP) | VAF 31/157 reads (20%) | catalogued as COSV100135837; called by muse, mutect2, varscan2
- EMILIN3 | c.402G>T p.T134= | Silent (SNP) | VAF 21/121 reads (17%) | catalogued as COSV100182751, COSV60035176; called by muse, mutect2, varscan2
- FLRT2 | c.1533G>A p.E511= | Silent (SNP) | VAF 38/146 reads (26%) | catalogued as COSV100420809; called by muse, mutect2, varscan2
- HINT2 | c.273C>A p.V91= | Silent (SNP) | VAF 22/77 reads (29%) | catalogued as COSV99428133; called by muse, mutect2, varscan2
- IMP4 | c.420C>T p.H140= | Silent (SNP) | VAF 25/58 reads (43%) | catalogued as rs201275845, COSV99383815; called by muse, mutect2, varscan2
- LILRA2 | c.867C>T p.H289= | Silent (SNP) | VAF 40/129 reads (31%) | catalogued as rs756841843, COSV52199849, COSV99063651; called by muse, mutect2, varscan2
- MS4A6E | c.421C>T p.L141= | Silent (SNP) | VAF 16/33 reads (48%) | catalogued as rs1220736529, COSV100279212; called by muse, mutect2, varscan2
- NUAK2 | c.471G>T p.R157= | Silent (SNP) | VAF 48/114 reads (42%) | catalogued as COSV100904130, COSV65682665; called by muse, mutect2, varscan2
- OR9G1 | c.639C>T p.I213= | Silent (SNP) | VAF 30/113 reads (27%) | catalogued as COSV100380512; called by muse, mutect2, varscan2
- RPLP2 | c.207G>T p.G69= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as COSV100337084; called by muse, mutect2, varscan2
- RPN2 | c.72G>T p.T24= | Silent (SNP) | VAF 23/136 reads (17%) | catalogued as COSV99411964; called by muse, mutect2, varscan2
- RPS6KA1 | c.2176C>A p.R726= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as COSV100943245; called by muse, mutect2, varscan2
- SAMD9 | c.525C>T p.Y175= | Silent (SNP) | VAF 24/79 reads (30%) | catalogued as rs757549728, COSV101180330; called by muse, mutect2, varscan2
- SCRN3 | c.1170A>G p.Q390= | Silent (SNP) | VAF 121/427 reads (28%) | catalogued as COSV99767420; called by muse, mutect2, varscan2
- SYCP2 | c.703C>T p.L235= | Silent (SNP) | VAF 11/160 reads (7%) | catalogued as COSV100698390; called by muse, mutect2
- TAFA1 | c.138G>A p.V46= | Silent (SNP) | VAF 12/107 reads (11%) | catalogued as COSV101524505; called by muse, mutect2
- TAS2R42 | c.36G>A p.L12= | Silent (SNP) | VAF 19/73 reads (26%) | catalogued as COSV100516908; called by muse, mutect2, varscan2
- TMC3 | c.2562T>A p.P854= | Silent (SNP) | VAF 13/112 reads (12%) | catalogued as COSV100845978; called by muse, mutect2, varscan2
- TNKS1BP1 | c.1500C>T p.I500= | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as COSV100836183, COSV64100103; called by muse, mutect2, varscan2
- TPGS1 | c.489G>A p.P163= | Silent (SNP) | VAF 21/46 reads (46%) | catalogued as COSV63764868; called by muse, mutect2, varscan2
- TPR | c.4752G>A p.R1584= | Silent (SNP) | VAF 9/72 reads (13%) | catalogued as rs1415846009, COSV100824181; called by muse, mutect2, varscan2
- TRERF1 | c.3465C>T p.P1155= | Silent (SNP) | VAF 28/96 reads (29%) | catalogued as COSV61676596; called by muse, mutect2, varscan2
- TRIP12 | c.4029G>A p.R1343= | Silent (SNP) | VAF 127/286 reads (44%) | catalogued as COSV99390777; called by muse, mutect2, varscan2
- VWA8 | c.1957T>C p.L653= | Silent (SNP) | VAF 9/86 reads (10%) | catalogued as COSV99864814; called by muse, mutect2, varscan2
- ZBTB12 | c.942G>A p.G314= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as COSV100977035; called by muse, mutect2, varscan2
- AC244258.1 | n.311-5005C>T | Intron (SNP) | VAF 7/37 reads (19%) | called by muse, mutect2
